Somatic mutation profile of tumor specimen ALCH-B01Z-TTR1-A (aliquot ALCH-B01Z-TTR1-A-2-0-D-A83F-36) from ALCHEMIST case ALCH-B01Z, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,709 days).
Specimen ALCH-B01Z-TTR1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0801d17-6a8e-4e77-a890-6c98f9407295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01Z-NB1-A (Blood Derived Normal), aliquot ALCH-B01Z-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49c70445-cc7e-422f-8c0e-01db6b0052be

The open-access MAF lists 50 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 12, Frame Shift Del 6, Splice Site 2, 3'UTR 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1orf87 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs148690695; called by muse, mutect2, varscan2
- COX11 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs766514764; called by muse, mutect2, varscan2
- GPC2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 39/179 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1454198259; called by muse, mutect2, varscan2
- IFNA21 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 59/370 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs778836854; called by muse, mutect2, varscan2
- IGHD6-25 | c.1G>A p.G1R | Missense Mutation (SNP) | VAF 47/234 reads (20%) | catalogued as rs376836850; called by muse, mutect2
- IGSF5 | c.956+1G>T p.X319_splice | Splice Site (SNP) | VAF 13/154 reads (8%) | catalogued as COSV66029970; called by muse, mutect2
- METTL7A | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs752350143; called by muse, mutect2, varscan2
- RAD21 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.091); catalogued as COSV52057097; called by muse, mutect2, varscan2
- RPS6KA4 | c.1549G>T p.V517L | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV53700523; called by muse, mutect2, varscan2
- SETD2 | c.6294-1G>A p.X2098_splice | Splice Site (SNP) | VAF 6/55 reads (11%) | catalogued as COSV57433558; called by muse, mutect2
- SYT1 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1297570788; called by muse, mutect2
- ARHGAP6 | c.1510T>A p.L504M | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATF7IP | c.1985_1989del p.K662Tfs*2 | Frame Shift Del (DEL) | VAF 28/87 reads (32%) | called by mutect2, pindel, varscan2
- BRD7 | c.432_441del p.M144Ifs*14 | Frame Shift Del (DEL) | VAF 41/158 reads (26%) | called by mutect2, pindel, varscan2
- CBX4 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPE | c.3214G>A p.D1072N | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- DNAH5 | c.5926G>A p.G1976R | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNLZ | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, varscan2
- ECHDC1 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FBXL3 | c.917A>T p.Y306F | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- FKBP15 | c.3128_3131del p.S1043Ffs*6 | Frame Shift Del (DEL) | VAF 14/117 reads (12%) | called by mutect2, pindel, varscan2
- GRAMD2B | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQGAP3 | c.2361del p.F787Lfs*8 | Frame Shift Del (DEL) | VAF 87/308 reads (28%) | called by mutect2, pindel, varscan2
- ITLN1 | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, varscan2
- MESP2 | c.776del p.P259Rfs*222 | Frame Shift Del (DEL) | VAF 44/101 reads (44%) | called by mutect2, pindel, varscan2
- PCDHA13 | c.1774G>C p.A592P | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- PCDHB7 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 28/764 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.034); called by muse, mutect2
- RAPGEF6 | c.896_900del p.E299Gfs*10 | Frame Shift Del (DEL) | VAF 29/267 reads (11%) | called by mutect2, pindel, varscan2
- SHISA7 | c.283dup p.T95Nfs*23 | Frame Shift Ins (INS) | VAF 24/246 reads (10%) | called by mutect2, pindel
- SIN3B | c.2069T>A p.L690Q | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- SLC29A2 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- SLC44A5 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TAGLN3 | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TEX11 | c.1019A>G p.N340S (on ENST00000344304; = p.N325S on NM_031276.3) | Missense Mutation (SNP) | VAF 79/118 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ZNF30 | c.1331C>G p.T444S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLIC6 | c.2016C>T p.Y672= (on ENST00000360731 / NM_001317009.2; = p.Y654= on NM_053277.3) | Silent (SNP) | VAF 50/184 reads (27%) | called by muse, mutect2, varscan2
- GLP2R | c.60C>T p.G20= | Silent (SNP) | VAF 76/267 reads (28%) | catalogued as rs774643540; called by muse, mutect2, varscan2
- LPA | c.3795G>A p.T1265= | Silent (SNP) | VAF 70/317 reads (22%) | called by muse, mutect2, varscan2
- PARP8 | c.690T>C p.F230= | Silent (SNP) | VAF 16/300 reads (5%) | called by muse, mutect2
- PAX4 | c.339C>T p.C113= | Silent (SNP) | VAF 34/424 reads (8%) | called by muse, mutect2
- RASA3 | c.75C>T p.P25= | Silent (SNP) | VAF 23/393 reads (6%) | catalogued as rs9525236; called by muse, mutect2
- REC8 | c.174C>T p.P58= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as rs756363583; called by muse, mutect2, varscan2
- RNF2 | c.294A>G p.R98= | Silent (SNP) | VAF 63/392 reads (16%) | called by muse, mutect2, varscan2
- SERPINF1 | c.717G>A p.V239= | Silent (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- SRD5A3 | c.786C>A p.I262= | Silent (SNP) | VAF 51/142 reads (36%) | called by muse, mutect2, varscan2
- TET1 | c.6210T>C p.A2070= | Silent (SNP) | VAF 15/188 reads (8%) | called by muse, mutect2
- WDR53 | c.834G>A p.Q278= | Silent (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- CFAP410 | c.144-1008G>A | Intron (SNP) | VAF 62/178 reads (35%) | catalogued as COSV100297244; called by muse, mutect2, varscan2
- QRICH2 | c.*107G>T | 3'UTR (SNP) | VAF 23/54 reads (43%) | called by muse, mutect2, varscan2
- ZNF689 | c.*5G>A | 3'UTR (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
